Somatic mutation profile of tumor specimen TCGA-D3-A5GL-06A (aliquot TCGA-D3-A5GL-06A-11D-A27K-08) from TCGA case TCGA-D3-A5GL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 75.5 years (27,568 days).
Specimen TCGA-D3-A5GL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 641cd800-8a27-4b83-a4b4-65040ed794af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A5GL-10A (Blood Derived Normal), aliquot TCGA-D3-A5GL-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39a11f9f-6d2a-424c-8dbd-4e106f086f38

The open-access MAF lists 502 somatic variants for this specimen: 342 protein-altering or splice-affecting, 150 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 308, Silent 150, Nonsense Mutation 15, Splice Site 7, Intron 6, Frame Shift Del 4, In Frame Del 3, Splice Region 3, RNA 2, 5'UTR 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs769569410, CM060776, COSV100216536; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4498G>C p.V1500L (on ENST00000272895 / NM_173076.3; = p.V1182L on NM_015657.3) | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs983344742, COSV99789693; called by muse, mutect2, varscan2
- ABCA8 | c.3932G>A p.G1311E | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV99285564; called by muse, mutect2, varscan2
- ABCB5 | c.1838G>A p.R613Q (on ENST00000404938 / NM_001163941.2; = p.R168Q on NM_178559.6) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1187222290, COSV51706928; called by muse, mutect2, varscan2
- ABCC12 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as COSV100252590; called by muse, mutect2, varscan2
- AC093525.2 | c.1072T>C p.W358R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | PolyPhen benign (0); catalogued as COSV53550210, COSV99565782; called by muse, mutect2, varscan2
- AC127029.3 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 104/257 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100033278; called by muse, mutect2, varscan2
- ADAM18 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.449); catalogued as COSV55844801, COSV99695436; called by muse, mutect2, varscan2
- ADAM7 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.194); catalogued as COSV99443762; called by muse, mutect2, varscan2
- ADSL | c.793-1G>T p.X265_splice | Splice Site (SNP) | VAF 75/344 reads (22%) | catalogued as COSV99342200; called by muse, mutect2, varscan2
- AHCYL2 | c.538T>A p.S180T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100273320; called by muse, mutect2, varscan2
- AHNAK | c.9850C>T p.P3284S | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99947127; called by muse, mutect2, varscan2
- AKAP8L | c.1592A>G p.N531S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99511891; called by muse, mutect2, varscan2
- AKR1D1 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99653015; called by muse, mutect2, varscan2
- AL136295.1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 101/284 reads (36%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.006); catalogued as rs1288026756, COSV99841699; called by muse, mutect2, varscan2
- ALB | c.37T>A p.F13I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV99891342; called by muse, mutect2, varscan2
- ANK3 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99779613; called by muse, mutect2, varscan2
- ANKRD11 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs765151001, COSV99969095; called by muse, mutect2, varscan2
- ANKRD11 | c.4000C>T p.P1334S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV99969096; called by muse, mutect2, varscan2
- ANKRD24 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99517407; called by mutect2, varscan2
- ANO9 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100240909; called by muse, mutect2
- APOBR | c.3055G>A p.E1019K (on ENST00000431282; = p.E1028K on NM_018690.4) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV60492079; called by muse, mutect2, varscan2
- APP | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244541473, COSV60999774; called by muse, mutect2, varscan2
- ARHGAP30 | c.2926G>A p.G976R (on ENST00000368013 / NM_001025598.2; = p.G765R on NM_181720.3) | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100920233; called by muse, mutect2, varscan2
- ARMC3 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as COSV99957930; called by muse, varscan2
- ARPP21 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as rs545003470, COSV51799381; called by muse, mutect2, varscan2
- ASXL3 | c.4591G>A p.E1531K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.096); catalogued as rs866215181, COSV99324654; called by muse, mutect2, varscan2
- ASXL3 | c.6550C>T p.P2184S | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); catalogued as COSV99324659; called by muse, mutect2, varscan2
- ATP8A1 | c.2851C>T p.H951Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1207967961, COSV100045872; called by muse, mutect2, varscan2
- ATP8A1 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100045876; called by muse, mutect2, varscan2
- BCL2 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.561); catalogued as COSV100384143; called by muse, mutect2, varscan2
- C17orf80 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as COSV99278016; called by muse, mutect2, varscan2
- C20orf194 | c.2186T>G p.V729G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99330651; called by muse, mutect2, varscan2
- CACNA1A | c.1732G>A p.G578R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100802146; called by muse, mutect2, varscan2
- CACNA1D | c.3971T>G p.M1324R (on ENST00000350061 / NM_001128840.3; = p.M1344R on NM_000720.4) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99857826; called by muse, mutect2
- CACNA1H | c.6578C>T p.S2193L | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748432349, COSV99326683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.5530G>A p.D1844N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as rs771184662, COSV60811494; called by muse, mutect2, varscan2
- CARD14 | c.1544G>C p.G515A | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV100712546; called by muse, mutect2, varscan2
- CASR | c.2530G>A p.E844K (on ENST00000490131; = p.E921K on NM_000388.4) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs755629322, COSV56136433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPERB | c.3005C>T p.P1002L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs777354519, COSV99831164; called by muse, mutect2, varscan2
- CATSPERB | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99831166; called by muse, mutect2, varscan2
- CATSPERB | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV99831168; called by muse, mutect2, varscan2
- CCL7 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.31); catalogued as COSV52337733, COSV99565530; called by muse, mutect2, varscan2
- CCM2 | c.555T>G p.S185R | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.571); catalogued as COSV99347729; called by muse, mutect2, varscan2
- CD248 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100256565, COSV100256854; called by muse, mutect2, varscan2
- CD5L | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100941043; called by muse, mutect2, varscan2
- CDH6 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV99418923; called by muse, mutect2, varscan2
- CDK13 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.344); catalogued as COSV99475421; called by muse, mutect2, varscan2
- CDYL2 | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV101629551; called by muse, mutect2, varscan2
- CER1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101097803, COSV66603357; called by muse, mutect2, varscan2
- CFAP100 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV61505002; called by muse, mutect2, varscan2
- CFAP54 | c.7115C>T p.S2372F | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs894088687, COSV61570780; called by muse, mutect2
- CFHR2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs1420958359, COSV100804392, COSV66381019; called by muse, mutect2, varscan2
- CHRM2 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.268); catalogued as COSV100281187, COSV57770532; called by muse, mutect2, varscan2
- CNN1 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99370643; called by muse, mutect2, varscan2
- COL11A1 | c.4465G>A p.G1489R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV62183742; called by muse, mutect2, varscan2
- COL11A2 | c.2002C>T p.P668S (on ENST00000341947 / NM_080680.3; = p.P561S on NM_080679.2) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as rs767657318, CM1310537, COSV100553862; called by muse, mutect2, varscan2
- COL12A1 | c.660G>A p.G220= | Splice Region (SNP) | VAF 15/24 reads (63%) | catalogued as COSV100485889; called by muse, mutect2, varscan2
- COL4A3 | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100516725; called by muse, mutect2, varscan2
- CPT1C | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99773407; called by muse, mutect2, varscan2
- CSMD2 | c.7103T>G p.I2368S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99589298; called by muse, mutect2, varscan2
- CSMD2 | c.4210G>A p.G1404S | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs200976511, COSV53914025; called by muse, mutect2, varscan2
- CSMD2 | c.2488T>C p.F830L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs1199215105, COSV99589303; called by muse, mutect2, varscan2
- CST5 | c.268T>A p.F90I | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV100489613; called by muse, mutect2, varscan2
- CTNNA3 | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs754896598, COSV101048722, COSV65551962; called by muse, mutect2, varscan2
- CYP2C9 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749060448, CM074766, COSV53250093; called by muse, mutect2, varscan2
- CYP4B1 | c.1129T>C p.Y377H | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99597072; called by muse, mutect2, varscan2
- DCC | c.3422G>A p.R1141K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.688); catalogued as rs1303874568, COSV71428013; called by muse, mutect2, varscan2
- DCSTAMP | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.047); catalogued as COSV52579623; called by muse, mutect2, varscan2
- DHX34 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV100169514; called by muse, mutect2, varscan2
- DIP2B | c.4101G>A p.K1367= | Splice Region (SNP) | VAF 34/106 reads (32%) | catalogued as COSV99998369; called by muse, mutect2, varscan2
- DMGDH | c.2192T>C p.M731T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV99668841; called by muse, mutect2, varscan2
- DNAH10 | c.970G>A p.V324I (on ENST00000409039; = p.V263I on NM_207437.3) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV101292195; called by muse, mutect2, varscan2
- DNAH10 | c.7943C>T p.S2648L (on ENST00000409039; = p.S2587L on NM_207437.3) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751315749, COSV68987215; called by muse, mutect2, varscan2
- DNAH2 | c.11038G>T p.E3680* | Nonsense Mutation (SNP) | VAF 55/150 reads (37%) | catalogued as COSV101209236; called by muse, mutect2, varscan2
- DNAH5 | c.12638A>C p.N4213T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99448952; called by muse, mutect2, varscan2
- DNAH7 | c.8405C>T p.S2802L | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV56750064; called by muse, mutect2, varscan2
- DNAH7 | c.6110A>G p.K2037R | Missense Mutation (SNP) | VAF 67/84 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV100414945; called by muse, mutect2, varscan2
- DRD5 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100431727, COSV99079686; called by muse, mutect2, varscan2
- DRICH1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100497431; called by muse, mutect2, varscan2
- DYNC1H1 | c.12915T>A p.F4305L | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV100794795; called by muse, mutect2, varscan2
- ELOVL1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773003850, COSV100196430; called by muse, mutect2, varscan2
- ENPEP | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV99487523; called by muse, mutect2, varscan2
- EPB41L4B | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs774922127, COSV101000902; called by muse, mutect2, varscan2
- EPHA6 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101062230; called by muse, mutect2, varscan2
- ERICH3 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV58600258; called by muse, mutect2, varscan2
- EXD1 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV100153593; called by muse, mutect2
- F13B | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.982); catalogued as COSV100803276; called by muse, mutect2, varscan2
- FAM120C | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.638); catalogued as COSV100069948; called by muse, mutect2, varscan2
- FAM135B | c.3346T>G p.L1116V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.918); catalogued as COSV52708161; called by muse, mutect2, varscan2
- FAM177B | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100680348; called by muse, mutect2, varscan2
- FAM90A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.679); catalogued as COSV100274284; called by muse, mutect2, varscan2
- FBH1 | c.781C>T p.R261* (on ENST00000362091 / NM_178150.3; = p.R312* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV62981896; called by muse, mutect2, varscan2
- FBLN5 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV50902110; called by muse, mutect2, varscan2
- FBXO21 | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs753805100, COSV100401703; called by muse, varscan2
- FCHO2 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as COSV100530564; called by muse, mutect2, varscan2
- FLRT2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368225812, COSV58140215; called by muse, mutect2, varscan2
- FNBP4 | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55447970; called by muse, mutect2, varscan2
- FRMD6 | c.869T>C p.L290S (on ENST00000344768 / NM_001267046.2; = p.L282S on NM_152330.4) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV100655745; called by muse, mutect2, varscan2
- GABRA3 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV100942636; called by muse, mutect2, varscan2
- GFOD2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99263523; called by muse, mutect2, varscan2
- GHRHR | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV100396563; called by muse, mutect2, varscan2
- GIMAP8 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs750008473, COSV56231017; called by muse, mutect2, varscan2
- GJC1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV100395159; called by muse, mutect2, varscan2
- GLRA3 | c.1264A>T p.I422F | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99927480; called by muse, mutect2, varscan2
- GLYATL1 | c.226C>T p.R76C (on ENST00000317391 / NM_001354699.1; = p.R107C on NM_080661.4) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs151204927, COSV55607318; called by muse, mutect2, varscan2
- GOPC | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99270901; called by muse, mutect2, varscan2
- GPC6 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100988546; called by muse, mutect2, varscan2
- GPCPD1 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1422762261, COSV66830844; called by muse, mutect2, varscan2
- GPR149 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67668719; called by muse, mutect2, varscan2
- GPX5 | c.360-1G>A p.X120_splice | Splice Site (SNP) | VAF 32/91 reads (35%) | catalogued as COSV101297257; called by muse, mutect2, varscan2
- GRM6 | c.778T>C p.F260L | Missense Mutation (SNP) | VAF 104/164 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1231762338, COSV99179581; called by muse, mutect2, varscan2
- GSE1 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99496440; called by muse, mutect2, varscan2
- GTF3C1 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850891; called by muse, mutect2, varscan2
- HBB | c.315G>A p.R105= | Splice Region (SNP) | VAF 28/79 reads (35%) | catalogued as rs33914944, CM044639, COSV100092736; called by muse, mutect2, varscan2
- HEATR5B | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT tolerated (0.74); PolyPhen benign (0.391); catalogued as rs1311557993, COSV99249136; called by muse, mutect2, varscan2
- HMGCLL1 | c.277A>T p.K93* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV51450374, COSV99231977; called by muse, mutect2, varscan2
- HMGXB4 | c.832C>G p.H278D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV53333782, COSV99330063; called by muse, mutect2, varscan2
- HPGDS | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99755645; called by muse, mutect2, varscan2
- HPGDS | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV99755648; called by muse, mutect2, varscan2
- HSF1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100184012; called by muse, mutect2, varscan2
- HYDIN | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs140028548; called by muse, mutect2, varscan2
- IFNE | c.431T>G p.V144G | Missense Mutation (SNP) | VAF 82/133 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV100438829; called by muse, mutect2, varscan2
- IGHV2-5 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.106); catalogued as rs782070162; called by muse, mutect2, varscan2
- IGSF9B | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100317496; called by muse, mutect2, varscan2
- IKZF4 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.636); catalogued as COSV100009051; called by muse, mutect2, varscan2
- IL17RC | c.596C>T p.S199F (on ENST00000295981 / NM_153461.4; = p.S128F on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55967839; called by muse, mutect2, varscan2
- ILDR1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56548770; called by muse, mutect2, varscan2
- ISM2 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV99376600; called by muse, mutect2, varscan2
- ITGAX | c.3422T>C p.M1141T | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV99191645; called by muse, mutect2, varscan2
- ITIH5 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs267602579, COSV99904481; called by muse, mutect2, varscan2
- ITPR1 | c.2287G>A p.D763N (on ENST00000354582; = p.D748N on NM_002222.7) | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1249327475, COSV100229470; called by muse, mutect2, varscan2
- JAML | c.550C>T p.R184C (on ENST00000356289 / NM_001098526.2; = p.R174C on NM_153206.3) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs774147626, COSV52627117, COSV52627225; called by muse, mutect2
- JMJD6 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1443788827, COSV100373027; called by muse, mutect2, varscan2
- JUP | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100159525; called by muse, mutect2, varscan2
- KCNH1 | c.1078C>T p.R360C (on ENST00000271751 / NM_172362.3; = p.R333C on NM_002238.4) | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55084722, COSV55099309; called by muse, mutect2, varscan2
- KCNU1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs751762536, COSV67753922; called by muse, mutect2, varscan2
- KIAA0319 | c.2636T>G p.V879G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100985503; called by muse, mutect2, varscan2
- KIAA0319 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV100985504, COSV65498248; called by muse, mutect2, varscan2
- KIF13A | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99435645; called by muse, mutect2, varscan2
- KIR3DL1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as COSV100428561; called by muse, mutect2, varscan2
- KLHL24 | c.1181A>T p.N394I | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as rs765278644, COSV99664879; called by muse, mutect2, varscan2
- KMT2D | c.15296G>A p.G5099D | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99980816; called by muse, mutect2, varscan2
- L3MBTL1 | c.1313G>A p.G438D (on ENST00000418998 / NM_001377303.1; = p.G348D on NM_015478.7) | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100916876, COSV100916984, COSV64228097; called by muse, mutect2, varscan2
- LAMA1 | c.3882G>A p.W1294* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV67534111; called by muse, mutect2, varscan2
- LILRB4 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs766142180, COSV54408647, COSV99553791; called by muse, mutect2, varscan2
- LINGO4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100561910; called by muse, mutect2, varscan2
- LRRC15 | c.1736A>T p.N579I | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100752675; called by muse, mutect2, varscan2
- LRRC30 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.142); catalogued as rs1322751104, COSV67302044; called by muse, mutect2, varscan2
- LRRC36 | c.2070T>G p.Y690* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV99338645; called by muse, mutect2, varscan2
- LRRC4B | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100975896; called by muse, mutect2, varscan2
- LSS | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100710886; called by muse, mutect2, varscan2
- MAP1B | c.7252-2A>G p.X2418_splice | Splice Site (SNP) | VAF 27/47 reads (57%) | catalogued as COSV99702244; called by muse, mutect2, varscan2
- MAP3K9 | c.2109C>A p.F703L (on ENST00000554752 / NM_001284230.1; = p.F717L on NM_033141.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101173609; called by muse, mutect2, varscan2
- MCTP1 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100387000, COSV56514336; called by muse, mutect2, varscan2
- MCTP2 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100537431; called by muse, mutect2, varscan2
- MED12L | c.3568A>G p.K1190E | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773200039, COSV99852746; called by muse, mutect2, varscan2
- METTL7A | c.136A>T p.I46L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100153667; called by muse, mutect2, varscan2
- MMP9 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.133); catalogued as COSV100812394; called by muse, mutect2, varscan2
- MMS22L | c.651A>G p.I217M | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99246656; called by muse, mutect2, varscan2
- MTARC1 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100856287; called by muse, mutect2, varscan2
- MUC16 | c.33935C>T p.S11312L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as rs1398617429, COSV101199595; called by muse, mutect2, varscan2
- MUC16 | c.18049G>A p.G6017R | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV101198084; called by muse, mutect2, varscan2
- MUC3A | c.7744C>T p.P2582S | Missense Mutation (SNP) | VAF 215/892 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.412); catalogued as rs776173116, COSV100114501; called by muse, mutect2, varscan2
- MYH3 | c.3729+1G>A p.X1243_splice | Splice Site (SNP) | VAF 45/142 reads (32%) | catalogued as COSV99878120; called by muse, mutect2, varscan2
- MYO18A | c.2980G>A p.G994S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.029); catalogued as rs572436360, COSV100572215; called by muse, mutect2, varscan2
- MYRF | c.431C>T p.S144F (on ENST00000278836 / NM_001127392.3; = p.S135F on NM_013279.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99606960; called by muse, mutect2, varscan2
- NAP1L3 | c.1454C>A p.T485N | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100220324; called by muse, varscan2
- NCEH1 | c.781T>G p.Y261D (on ENST00000538775; = p.Y221D on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99860037; called by muse, mutect2, varscan2
- NCOA7 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs1290494178, COSV99996936; called by muse, mutect2, varscan2
- NEURL1 | c.299T>G p.V100G | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100872744; called by muse, mutect2, varscan2
- NEXMIF | c.2426T>G p.V809G | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50069919; called by muse, mutect2, varscan2
- NFAT5 | c.1077A>T p.E359D | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100590709; called by muse, mutect2, varscan2
- NINJ2 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV99842903; called by muse, mutect2, varscan2
- NLGN4Y | c.1715T>G p.I572S | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100196730; called by muse, mutect2, varscan2
- NLRP2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200257622, COSV99672225; called by muse, mutect2, varscan2
- NOCT | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV99763831; called by muse, mutect2, varscan2
- NOL8 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100694526; called by muse, mutect2, varscan2
- NOX5 | c.1988A>T p.E663V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as COSV99533750; called by muse, mutect2
- NPHP3 | c.2362A>G p.M788V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100446850, COSV58629526; called by muse, mutect2, varscan2
- NRG1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs78513616, CM133118; called by muse, mutect2, varscan2
- NRG1 | c.400+1G>A p.X134_splice | Splice Site (SNP) | VAF 35/98 reads (36%) | catalogued as COSV99828306; called by muse, mutect2, varscan2
- NRIP1 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535553992, COSV100012622; called by muse, mutect2, varscan2
- NRXN3 | c.2584C>T p.R862C (on ENST00000335750 / NM_001330195.2; = p.R489C on NM_004796.6) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1275495927, COSV100203243; called by muse, mutect2, varscan2
- NSUN7 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57276272; called by muse, mutect2, varscan2
- NSUN7 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1010236754, COSV57275248; called by muse, mutect2, varscan2
- NT5DC2 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV58741063; called by muse, mutect2, varscan2
- NTPCR | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545375836, COSV100786709; called by muse, mutect2, varscan2
- NTSR1 | c.1039A>C p.M347L | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100980644; called by muse, mutect2, varscan2
- NUF2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99616402; called by muse, mutect2, varscan2
- OAS3 | c.2860C>T p.Q954* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as rs1486966574, COSV99966231; called by muse, mutect2, varscan2
- OBSCN | c.4414G>A p.E1472K | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.949); catalogued as COSV52737475; called by muse, mutect2, varscan2
- OLR1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV100376354; called by muse, mutect2, varscan2
- OR11H12 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs778510222, COSV101612483; called by muse, mutect2, varscan2
- OR13C3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs369932733; called by muse, mutect2, varscan2
- OR14A16 | c.581A>T p.E194V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV100713763; called by muse, mutect2, varscan2
- OR1N1 | c.181T>A p.L61M | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100509728; called by muse, mutect2, varscan2
- OR2T1 | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100822301; called by muse, mutect2, varscan2
- OR2T4 | c.904A>T p.K302* | Nonsense Mutation (SNP) | VAF 79/198 reads (40%) | catalogued as COSV100822470; called by muse, mutect2, varscan2
- OR4A47 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101487063, COSV71444879, COSV71445121; called by muse, mutect2, varscan2
- OR4C15 | c.379T>C p.S127P (on ENST00000314644; = p.S73P on NM_001001920.2) | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV58951546, COSV58952166; called by muse, mutect2
- OR51T1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs200553277, COSV100434335, COSV59024390; called by muse, mutect2, varscan2
- OR52R1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs200914402, COSV61887825; called by muse, mutect2, varscan2
- OR5AK2 | c.864A>T p.L288F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs767694663, COSV100476011; called by muse, mutect2, varscan2
- OR5H6 | c.403G>A p.A135T (on ENST00000642105; = p.A119T on NM_001005479.2) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1284172687, COSV67351144; called by muse, mutect2, varscan2
- OR6C70 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.168); catalogued as COSV59244428; called by muse, mutect2
- ORC1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.687); catalogued as rs373671398; called by muse, mutect2, varscan2
- OTOGL | c.6595G>A p.G2199R (on ENST00000547103; = p.G2190R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54016058; called by muse, mutect2
- PADI4 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100966771; called by muse, mutect2, varscan2
- PAPPA2 | c.4773T>G p.I1591M | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100867956; called by muse, mutect2
- PARD3 | c.3707C>T p.S1236F | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs772939644, COSV100631810; called by muse, mutect2, varscan2
- PCDHA7 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs782278654, COSV65343131; called by muse, mutect2, varscan2
- PCDHB2 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52031260; called by muse, mutect2, varscan2
- PCDHGA11 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99038468, COSV99536777; called by muse, mutect2, varscan2
- PHF7 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 68/99 reads (69%) | catalogued as COSV100015404; called by muse, mutect2, varscan2
- PIAS1 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV99986729; called by muse, mutect2, varscan2
- PIGO | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99956619; called by muse, mutect2, varscan2
- PIK3C2G | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.006); catalogued as COSV56815008; called by muse, mutect2, varscan2
- PLCB4 | c.2096T>A p.I699N | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99595258; called by muse, mutect2, varscan2
- PLEKHA6 | c.2543G>A p.S848N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV55339977, COSV99691913; called by muse, mutect2, varscan2
- PNN | c.820T>A p.F274I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as COSV99397161; called by muse, mutect2, varscan2
- POU4F1 | c.222T>A p.H74Q | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV101020530; called by muse, mutect2, varscan2
- PPIP5K1 | c.3799C>T p.P1267S (on ENST00000396923; = p.P1242S on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs768801879, COSV100288563; called by muse, mutect2, varscan2
- PPL | c.4297G>T p.E1433* | Nonsense Mutation (SNP) | VAF 81/193 reads (42%) | catalogued as rs889396569, COSV99277889; called by muse, mutect2, varscan2
- PPP4R4 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV100428548; called by muse, mutect2, varscan2
- PRAMEF10 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 99/355 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.306); catalogued as rs1237769184; called by muse, mutect2, varscan2
- PRB4 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 157/369 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.071); catalogued as COSV99686484; called by muse, mutect2, varscan2
- PRDM9 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs755272851, COSV57001938, COSV57008058; called by muse, mutect2, varscan2
- PRICKLE1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100566302; called by muse, mutect2, varscan2
- PRKCB | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as rs868712349, COSV57767898; called by muse, mutect2, varscan2
- PRR15L | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99846498; called by muse, mutect2, varscan2
- PRR16 | c.538G>A p.D180N (on ENST00000407149 / NM_001300783.2; = p.D157N on NM_016644.2) | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101086948, COSV101088218; called by muse, mutect2, varscan2
- PRR23B | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as COSV100272039, COSV61494846; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.949C>T p.R317W (on ENST00000421990 / NM_001136042.2; = p.R299W on NM_025267.3) | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs574315993, COSV64182118; called by muse, mutect2, varscan2
- PTPRA | c.2059C>T p.R687W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs575162120, COSV99399690; called by muse, mutect2, varscan2
- PTPRB | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.165); catalogued as COSV99317220; called by muse, mutect2, varscan2
- PTPRK | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868427142, COSV63894383; called by muse, mutect2, varscan2
- RAB3IP | c.225T>G p.D75E (on ENST00000550536 / NM_175623.4; = p.D59E on NM_022456.5) | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.049); catalogued as COSV99923158; called by muse, mutect2, varscan2
- RAG1 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100200853; called by muse, mutect2, varscan2
- RAG2 | c.940A>T p.S314C | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV100271255; called by muse, mutect2, varscan2
- RALGPS2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.337); catalogued as COSV100243842; called by muse, mutect2, varscan2
- RAPGEF5 | c.1659A>T p.L553F (on ENST00000401957 / NM_001367602.2; = p.L856F on NM_012294.5) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100686914; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.986); catalogued as COSV99228895; called by muse, mutect2, varscan2
- RASGEF1C | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267600584, COSV100745887; called by muse, varscan2
- RFX3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs1419148840, COSV100174964; called by muse, mutect2, varscan2
- RIMS1 | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53460200; called by muse, mutect2, varscan2
- RPGRIP1 | c.2558T>G p.F853C | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99250930; called by muse, mutect2, varscan2
- RUNX1T1 | c.1429G>A p.D477N (on ENST00000265814 / NM_001198628.1; = p.D450N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs569622614, COSV56148600; called by muse, mutect2, varscan2
- SBF2 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.155); catalogued as rs1488184850, COSV99814016; called by muse, mutect2, varscan2
- SCN4A | c.5103G>A p.M1701I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.865); catalogued as COSV101438454; called by muse, mutect2, varscan2
- SCNN1B | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 54/125 reads (43%) | catalogued as rs867839006, COSV56311669; called by muse, mutect2, varscan2
- SEL1L2 | c.1984A>C p.T662P | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.399); catalogued as COSV99533080; called by muse, mutect2, varscan2
- SEMA3C | c.293T>G p.V98G | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as COSV99542863; called by muse, mutect2, varscan2
- SEMA3D | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV99406467; called by muse, mutect2, varscan2
- SERPINA4 | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100097150; called by muse, mutect2, varscan2
- SHANK1 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV99521006; called by muse, mutect2, varscan2
- SHANK2 | c.3909G>A p.M1303I | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs782652221, COSV99573578; called by muse, mutect2, varscan2
- SIAH2 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as COSV100469222; called by muse, mutect2, varscan2
- SIX4 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV99382190; called by muse, mutect2, varscan2
- SLC22A9 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs143461929, COSV54169664; called by muse, varscan2
- SLC26A3 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs746185703, COSV60638639; called by muse, mutect2, varscan2
- SLC39A10 | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100660586; called by muse, mutect2, varscan2
- SLC4A7 | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99839643; called by muse, mutect2, varscan2
- SLC6A5 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1197374743, COSV100116818, COSV54229964; called by muse, mutect2, varscan2
- SLC7A9 | c.1305G>A p.W435* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV50083576, COSV99195268; called by muse, mutect2, varscan2
- SLC8A3 | c.885T>G p.H295Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.995); catalogued as COSV100776123; called by muse, mutect2, varscan2
- SLITRK3 | c.2896T>C p.Y966H | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99579108; called by muse, mutect2, varscan2
- SMAD2 | c.944T>G p.L315* | Nonsense Mutation (SNP) | VAF 43/104 reads (41%) | catalogued as COSV100053625, COSV51029739; called by muse, mutect2, varscan2
- SNTG1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV52466156, COSV99383278, COSV99386101; called by muse, mutect2, varscan2
- SORBS1 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53355699; called by muse, mutect2, varscan2
- STAB1 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 70/99 reads (71%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV58735566; called by muse, mutect2, varscan2
- STAB2 | c.1666T>A p.F556I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101185898; called by muse, mutect2, varscan2
- STAB2 | c.4378G>A p.A1460T | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV101185900; called by muse, mutect2, varscan2
- STRIP2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.454); catalogued as COSV99973753; called by muse, mutect2, varscan2
- SVEP1 | c.8425G>A p.G2809S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253604337, COSV52841923; called by muse, mutect2, varscan2
- SVEP1 | c.8255C>T p.S2752F | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs774501316, COSV99928892; called by muse, mutect2, varscan2
- TAF4B | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs758560400, COSV99300120; called by muse, mutect2, varscan2
- TAS2R60 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as COSV100223532; called by muse, mutect2
- TASOR | c.2984A>G p.E995G (on ENST00000355628 / NM_001365636.2; = p.E619G on NM_015224.3) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV100843508; called by muse, mutect2, varscan2
- TENM3 | c.910T>C p.Y304H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV101305069; called by muse, mutect2, varscan2
- TEP1 | c.434A>T p.N145I | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as COSV99402212; called by muse, mutect2, varscan2
- TG | c.7409T>G p.L2470R | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99600478; called by muse, mutect2, varscan2
- TGM6 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99171767; called by muse, mutect2, varscan2
- TGM7 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101476846; called by muse, mutect2, varscan2
- THAP6 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs1032001251, COSV100185814; called by muse, mutect2, varscan2
- THBS1 | c.1078A>G p.N360D | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99527879; called by muse, mutect2, varscan2
- TLL1 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.992); catalogued as COSV99285671; called by muse, mutect2, varscan2
- TLR4 | c.1683dup p.Q562Tfs*9 (on ENST00000355622 / NM_138554.5; = p.Q522Tfs*9 on NM_003266.4) | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | catalogued as rs759923416; called by mutect2, pindel, varscan2
- TMEM156 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.801); catalogued as COSV60744090; called by muse, mutect2, varscan2
- TMPRSS11D | c.1001A>T p.N334I | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99384631; called by muse, mutect2, varscan2
- TNS1 | c.2506C>G p.P836A | Missense Mutation (SNP) | VAF 84/97 reads (87%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV99410530; called by muse, mutect2, varscan2
- TNS2 | c.289A>G p.I97V (on ENST00000314250 / NM_170754.4; = p.I107V on NM_015319.2) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.456); catalogued as COSV100047975; called by muse, mutect2, varscan2
- TPH2 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1431959572, COSV100421852, COSV61590905; called by muse, mutect2, varscan2
- TRA2B | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV99373245; called by muse, mutect2, varscan2
- TRANK1 | c.5275G>A p.E1759K | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100082638; called by muse, mutect2, varscan2
- TRIML2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV58718093; called by muse, mutect2, varscan2
- TRIOBP | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV60379602; called by muse, mutect2, varscan2
- TRPV5 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99520450; called by muse, mutect2, varscan2
- TST | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99968184; called by muse, mutect2, varscan2
- TTPA | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99478491; called by muse, mutect2, varscan2
- UGT1A6 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 154/187 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as COSV100530011; called by muse, mutect2, varscan2
- UGT3A1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs771386938, COSV99954662; called by muse, varscan2
- UNC5B | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 123/323 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100100673; called by muse, mutect2, varscan2
- UNC93B1 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs766907412, COSV99916359; called by muse, mutect2, varscan2
- USH2A | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV100233503, COSV56384095; called by muse, mutect2, varscan2
- UVRAG | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs780023573, COSV62106349; called by muse, mutect2
- VCL | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.54); catalogued as rs1251509217, COSV99280741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR59 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100049245; called by muse, mutect2, varscan2
- WT1 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV100187968, COSV60067845; called by muse, varscan2
- ZBTB17 | c.944T>C p.F315S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100999006; called by muse, mutect2, varscan2
- ZBTB43 | c.1293T>A p.N431K | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.312); catalogued as COSV100991353; called by muse, mutect2, varscan2
- ZFP28 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as rs778731671, COSV100019518; called by muse, mutect2, varscan2
- ZFP69B | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100848246; called by muse, mutect2, varscan2
- ZMYM6 | c.3935C>T p.S1312F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100593147, COSV64122757; called by muse, mutect2, varscan2
- ZNF212 | c.1225A>T p.N409Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100242351; called by muse, mutect2, varscan2
- ZNF284 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.715); catalogued as rs776923834, COSV101398970; called by muse, mutect2, varscan2
- ZNF324B | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.22); PolyPhen benign (0.23); catalogued as rs1436003381, COSV60742336; called by muse, mutect2, varscan2
- ZNF382 | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99497744; called by muse, mutect2, varscan2
- ZNF391 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV99772340; called by muse, mutect2, varscan2
- ZNF41 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.579); catalogued as COSV100492007; called by muse, mutect2, varscan2
- ZNF513 | c.1348A>G p.N450D | Missense Mutation (SNP) | VAF 240/301 reads (80%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as COSV99277515; called by muse, mutect2, varscan2
- ZNF524 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99684555; called by muse, mutect2, varscan2
- ZNF585A | c.649A>T p.S217C (on ENST00000292841 / NM_001288800.2; = p.S162C on NM_152655.3) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99493050; called by muse, mutect2, varscan2
- ZNF585B | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.567); catalogued as COSV57217197; called by muse, mutect2, varscan2
- ZNF610 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs762894343, COSV58345455, COSV58346895; called by muse, mutect2, varscan2
- ZNF700 | c.1474C>T p.H492Y | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1343025059, COSV99583481; called by muse, mutect2, varscan2
- ZNF804A | c.2732C>T p.S911F | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV56436542, COSV56436891, COSV56442291; called by muse, mutect2, varscan2
- ZSCAN31 | c.1051T>C p.Y351H | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100716966; called by muse, mutect2, varscan2
- ZSWIM5 | c.3184C>T p.P1062S | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as COSV99870144; called by muse, mutect2, varscan2
- ZZEF1 | c.2725C>A p.P909T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101067746; called by muse, mutect2, varscan2
- ARID2 | c.351_366del p.P118Lfs*92 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- CISD1 | c.93_116del p.K32_H39del | In Frame Del (DEL) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- EBF2 | c.704del p.N235Tfs*61 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, pindel, varscan2
- IGHV1-3 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- IGSF10 | c.5815del p.T1939Pfs*5 | Frame Shift Del (DEL) | VAF 51/151 reads (34%) | called by mutect2, pindel, varscan2
- NRBF2 | c.577del p.R193Gfs*7 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- PALLD | c.1478-2A>C p.X493_splice | Splice Site (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2
- PCSK9 | c.1864-1G>A p.X622_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2
- PIP4K2B | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PRAMEF6 | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by mutect2, varscan2
- PSME3IP1 | c.273_275del p.D91del | In Frame Del (DEL) | VAF 18/61 reads (30%) | called by pindel, varscan2
- PTBP2 | c.978_995del p.A327_A332del (on ENST00000426398 / NM_001300986.2; = p.A319_A324del on NM_021190.4) | In Frame Del (DEL) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- ACAN | c.99C>T p.I33= | Silent (SNP) | VAF 67/181 reads (37%) | catalogued as COSV61363906; called by muse, mutect2, varscan2
- ACAN | c.1119G>A p.Q373= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV100717897; called by muse, mutect2, varscan2
- ACAN | c.2187C>T p.I729= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100717899; called by muse, mutect2, varscan2
- ADGRB1 | c.1908C>T p.S636= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs1248141310, COSV60098354; called by muse, mutect2, varscan2
- ADGRL2 | c.2178C>T p.F726= (on ENST00000370717 / NM_001366005.1; = p.F713= on NM_012302.4) | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs752557639, COSV99587417; called by muse, mutect2, varscan2
- AL645922.1 | c.174C>T p.S58= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs753987052, COSV54960666; called by muse, mutect2, varscan2
- ALOXE3 | c.1824C>T p.S608= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100559682; called by muse, mutect2, varscan2
- ANK2 | c.11451C>T p.S3817= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV100001217; called by muse, mutect2, varscan2
- ANK3 | c.1530G>A p.G510= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as COSV99779609; called by muse, mutect2, varscan2
- APOB | c.786G>A p.K262= | Silent (SNP) | VAF 41/53 reads (77%) | catalogued as rs780876397, COSV99265289; called by muse, mutect2, varscan2
- ARFGAP3 | c.117C>T p.T39= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV54315012, COSV99605253; called by muse, mutect2, varscan2
- ARG1 | c.33T>A p.I11= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV99256086; called by muse, mutect2, varscan2
- ARHGEF15 | c.1899G>A p.R633= | Silent (SNP) | VAF 84/261 reads (32%) | catalogued as COSV100730034; called by muse, mutect2, varscan2
- ARID2 | c.2352T>A p.P784= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100536008; called by muse, mutect2, varscan2
- ASPH | c.1239T>C p.D413= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV101063790; called by muse, mutect2, varscan2
- ATP13A2 | c.2283C>T p.A761= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV100454111; called by muse, mutect2, varscan2
- BCS1L | c.948G>A p.L316= | Silent (SNP) | VAF 117/146 reads (80%) | catalogued as COSV99828955; called by muse, mutect2, varscan2
- BDP1 | c.6870G>A p.L2290= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV100702993; called by muse, mutect2, varscan2
- BUB3 | c.366G>A p.L122= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100922177; called by muse, mutect2, varscan2
- C4orf46 | c.306G>A p.L102= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100309908; called by muse, mutect2, varscan2
- CAGE1 | c.2166C>T p.S722= (on ENST00000512086; = p.S586= on NM_205864.3) | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV57078111; called by muse, mutect2, varscan2
- CARD18 | c.90A>G p.L30= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as COSV101596030; called by muse, mutect2, varscan2
- CASZ1 | c.816C>T p.T272= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV100681245; called by muse, mutect2, varscan2
- CCDC178 | c.1104G>A p.K368= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs138698300, COSV55786278; called by muse, mutect2, varscan2
- CDH6 | c.1435C>T p.L479= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV99418926; called by muse, mutect2, varscan2
- CDH7 | c.771T>C p.D257= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100542166; called by muse, mutect2, varscan2
- CDR1 | c.210G>T p.S70= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100983402, COSV65164850; called by muse, mutect2, varscan2
- CDX4 | c.132C>T p.F44= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as COSV65171586; called by muse, mutect2, varscan2
- CEACAM20 | c.495C>T p.I165= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as rs1019878370, COSV100386861, COSV100386892; called by muse, mutect2
- CFAP47 | c.855C>T p.I285= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as rs766257154, COSV99934897; called by muse, varscan2
- CHRM5 | c.480C>T p.I160= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as COSV101271920; called by muse, mutect2, varscan2
- CLEC14A | c.870G>A p.G290= | Silent (SNP) | VAF 63/135 reads (47%) | catalogued as rs1486956386, COSV60563683; called by muse, mutect2, varscan2
- CLEC4C | c.633C>T p.I211= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV100665432, COSV100665568; called by muse, mutect2, varscan2
- CLOCK | c.2061C>A p.T687= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV100011739; called by muse, mutect2, varscan2
- CNTN4 | c.1335G>A p.R445= | Silent (SNP) | VAF 37/54 reads (69%) | catalogued as COSV61870034; called by muse, mutect2, varscan2
- CNTNAP2 | c.2196C>T p.I732= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs769830314, COSV62192120, COSV62206510; called by muse, mutect2, varscan2
- COL21A1 | c.1668G>A p.K556= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1051535042, COSV99778487; called by muse, mutect2, varscan2
- CST5 | c.267G>A p.K89= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as rs779291957, COSV100489614; called by muse, mutect2, varscan2
- DDX60 | c.3516A>G p.K1172= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV101190430; called by muse, mutect2, varscan2
- DEPDC5 | c.3609C>T p.L1203= (on ENST00000400246; = p.L1272= on NM_014662.5) | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as rs545389943, COSV56702446; called by muse, mutect2, varscan2
- DHX34 | c.2442C>T p.V814= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV100169511; called by muse, mutect2, varscan2
- DISP1 | c.1455C>T p.T485= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs769827053, COSV52663039; called by muse, mutect2, varscan2
- DMBT1 | c.2118C>T p.S706= | Silent (SNP) | VAF 140/402 reads (35%) | catalogued as COSV100352835; called by muse, mutect2, varscan2
- DNAH10 | c.5676C>T p.A1892= (on ENST00000409039; = p.A1831= on NM_207437.3) | Silent (SNP) | VAF 56/185 reads (30%) | catalogued as rs749292496, COSV68998182; called by muse, mutect2, varscan2
- DNAH3 | c.783G>A p.L261= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as COSV99766959; called by muse, mutect2, varscan2
- DNAH7 | c.10752C>T p.F3584= | Silent (SNP) | VAF 55/73 reads (75%) | catalogued as COSV100417516, COSV56760945; called by muse, mutect2, varscan2
- DSP | c.7896C>T p.S2632= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as COSV65792619; called by muse, mutect2, varscan2
- ELAPOR1 | c.570C>T p.N190= | Silent (SNP) | VAF 65/182 reads (36%) | catalogued as COSV100884667; called by muse, mutect2, varscan2
- ELOVL1 | c.159G>A p.R53= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100196428; called by muse, mutect2, varscan2
- FAM114A2 | c.684C>A p.T228= | Silent (SNP) | VAF 19/25 reads (76%) | catalogued as COSV100697656; called by muse, mutect2, varscan2
- FER1L6 | c.792G>A p.A264= | Silent (SNP) | VAF 99/245 reads (40%) | catalogued as rs368591561; called by muse, mutect2, varscan2
- FKTN | c.834G>A p.K278= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs1273553951, COSV99795365; called by muse, mutect2, varscan2
- FPR1 | c.618C>T p.F206= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV100494045; called by muse, mutect2, varscan2
- GGT1 | c.300A>G p.K100= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV99958815; called by muse, mutect2, varscan2
- GMIP | c.2193C>T p.I731= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as rs1388317032, COSV99179178; called by muse, mutect2, varscan2
- GRAMD1B | c.1614G>A p.T538= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs761314687, COSV100454644; called by muse, varscan2
- GRIK3 | c.261C>T p.H87= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as rs199543796, COSV100901884; called by muse, mutect2, varscan2
- HAPLN4 | c.573C>T p.I191= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV52268665; called by muse, mutect2, varscan2
- HECW2 | c.1716G>A p.E572= | Silent (SNP) | VAF 50/67 reads (75%) | catalogued as COSV99646911; called by muse, mutect2, varscan2
- HNRNPL | c.600G>A p.L200= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as COSV99670247; called by muse, mutect2, varscan2
- HOGA1 | c.633G>A p.K211= | Silent (SNP) | VAF 107/298 reads (36%) | catalogued as rs758122412, COSV65706729; called by muse, mutect2, varscan2
- HOOK2 | c.804G>A p.E268= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99317511; called by muse, mutect2, varscan2
- IGSF21 | c.1068G>A p.G356= | Silent (SNP) | VAF 68/205 reads (33%) | catalogued as COSV99244579; called by muse, mutect2, varscan2
- IGSF9B | c.654C>T p.V218= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100317499; called by muse, mutect2, varscan2
- INSR | c.516C>T p.I172= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV57163811; called by muse, mutect2, varscan2
- INTS2 | c.2109G>A p.L703= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1397950301, COSV99248048; called by muse, mutect2
- ITPRID1 | c.1644T>C p.H548= | Silent (SNP) | VAF 80/203 reads (39%) | catalogued as COSV100086273; called by muse, mutect2, varscan2
- JAK1 | c.796C>T p.L266= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100691603; called by muse, mutect2, varscan2
- KCNAB3 | c.855C>T p.Y285= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs749016898, COSV100376015; called by muse, mutect2, varscan2
- KIF5A | c.1077G>A p.T359= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs552427920, COSV54058468, COSV99673334; called by muse, mutect2, varscan2
- KIR3DL1 | c.771G>A p.R257= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV100428560; called by muse, mutect2, varscan2
- KSR2 | c.1020G>A p.K340= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100194936; called by muse, mutect2, varscan2
- LGI4 | c.1503C>T p.A501= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV100032468; called by muse, mutect2, varscan2
- LMX1A | c.1005C>T p.F335= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV99672119; called by muse, mutect2, varscan2
- LRRC37B | c.2547G>A p.L849= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100496225; called by muse, mutect2, varscan2
- MAP3K15 | c.618C>T p.S206= | Silent (SNP) | VAF 27/34 reads (79%) | catalogued as rs1014898916, COSV100134608; called by muse, mutect2, varscan2
- MAP3K6 | c.3423C>T p.S1141= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs776729982, COSV100539287; called by muse, mutect2, varscan2
- MAZ | c.618G>A p.R206= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1425217750, COSV50713908; called by muse, mutect2, varscan2
- MDGA1 | c.2706G>A p.G902= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV99776779; called by muse, mutect2, varscan2
- MTNR1A | c.261G>A p.S87= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs773877086, COSV56154736; called by muse, mutect2, varscan2
- MUC16 | c.8502G>A p.T2834= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs908281742, COSV67445873; called by muse, mutect2, varscan2
- MYO3B | c.3315G>A p.R1105= | Silent (SNP) | VAF 31/36 reads (86%) | catalogued as COSV100510060; called by muse, mutect2, varscan2
- NCBP1 | c.312T>C p.F104= | Silent (SNP) | VAF 42/66 reads (64%) | catalogued as COSV100912584; called by muse, mutect2, varscan2
- NCKAP1L | c.1965G>A p.E655= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as rs767158636, COSV53214586; called by muse, mutect2, varscan2
- NEFL | c.354G>A p.L118= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1399426130, COSV99647959; called by muse, mutect2, varscan2
- NEIL2 | c.33C>T p.H11= | Silent (SNP) | VAF 50/102 reads (49%) | catalogued as rs1233918298, COSV99462218; called by muse, mutect2, varscan2
- NOCT | c.618C>T p.L206= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs762609219, COSV54935484, COSV99763830; called by muse, mutect2, varscan2
- NPHS1 | c.852G>A p.P284= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs763233132, COSV62286544; called by muse, mutect2, varscan2
- NPSR1 | c.1035A>G p.R345= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as COSV100706216; called by muse, mutect2, varscan2
- NPY4R | c.240C>T p.I80= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs546342201, COSV100966155; called by muse, mutect2, varscan2
- NWD1 | c.954C>T p.L318= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV60345966; called by muse, mutect2, varscan2
- NYNRIN | c.3843G>A p.E1281= | Silent (SNP) | VAF 57/152 reads (38%) | catalogued as COSV101230578, COSV66841096; called by muse, mutect2, varscan2
- NYNRIN | c.4152C>T p.L1384= | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as COSV66843875; called by muse, mutect2, varscan2
- OPRK1 | c.750C>T p.I250= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV55574325, COSV99653553; called by muse, mutect2, varscan2
- OR2B11 | c.342G>A p.T114= | Silent (SNP) | VAF 66/131 reads (50%) | catalogued as rs751779555, COSV100276508, COSV59511140; called by muse, mutect2, varscan2
- PCDH11Y | c.2535C>T p.I845= (on ENST00000400457 / NM_032973.2; = p.I834= on NM_032971.3) | Silent (SNP) | VAF 35/50 reads (70%) | catalogued as COSV99291269; called by muse, mutect2, varscan2
- PCDH17 | c.3270C>T p.F1090= | Silent (SNP) | VAF 112/149 reads (75%) | catalogued as rs267603852, COSV100931577; called by muse, mutect2, varscan2
- PCDHA5 | c.1203G>A p.K401= | Silent (SNP) | VAF 71/137 reads (52%) | catalogued as rs895281172, COSV100972242; called by muse, mutect2, varscan2
- PCDHGB1 | c.1533C>T p.F511= | Silent (SNP) | VAF 48/72 reads (67%) | catalogued as COSV53957555; called by muse, mutect2, varscan2
- PCLO | c.3471G>A p.V1157= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV61665603; called by muse, mutect2, varscan2
- PIK3C2G | c.225G>A p.G75= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV99851277; called by muse, mutect2, varscan2
- PIK3R5 | c.591C>T p.L197= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs530065110, COSV99353246; called by muse, mutect2, varscan2
- PIK3R6 | c.474C>T p.F158= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs374473647; called by muse, mutect2, varscan2
- PLA2G4F | c.2133C>T p.A711= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV99300595; called by muse, mutect2, varscan2
- PLCB4 | c.2517G>A p.K839= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV53792794, COSV53812438; called by muse, mutect2, varscan2
- PLD2 | c.210G>A p.V70= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs774977253, COSV99562303; called by muse, mutect2, varscan2
- PM20D1 | c.48C>A p.L16= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100900175; called by muse, mutect2, varscan2
- PNPLA7 | c.1080C>T p.S360= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV99480538; called by muse, mutect2, varscan2
- PRAMEF6 | c.967C>T p.L323= | Silent (SNP) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- PRKACG | c.855C>T p.L285= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as rs774072896, COSV99598630; called by muse, mutect2, varscan2
- RAB3IP | c.783C>T p.S261= (on ENST00000550536 / NM_175623.4; = p.S245= on NM_022456.5) | Silent (SNP) | VAF 70/118 reads (59%) | catalogued as COSV99923161; called by muse, mutect2, varscan2
- RNF40 | c.1986C>T p.A662= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100222042; called by muse, mutect2, varscan2
- SCAF1 | c.2628C>T p.F876= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs1242683943, COSV100862138; called by muse, mutect2, varscan2
- SDCBP2 | c.267G>A p.P89= (on ENST00000339987 / NM_001199784.1; = p.P4= on NM_015685.5) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs141940205; called by muse, varscan2
- SECISBP2 | c.945C>T p.A315= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as COSV100368638; called by muse, mutect2, varscan2
- SLC19A1 | c.72C>T p.S24= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100229281; called by muse, mutect2, varscan2
- SLC30A10 | c.657C>T p.T219= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100751486; called by muse, mutect2, varscan2
- SLC5A9 | c.1098C>T p.S366= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs1043014320, COSV99361594; called by muse, mutect2, varscan2
- SLC6A11 | c.789C>T p.I263= | Silent (SNP) | VAF 29/214 reads (14%) | catalogued as COSV99594291; called by muse, mutect2, varscan2
- SLC6A18 | c.216C>T p.F72= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99722256; called by muse, mutect2, varscan2
- SLCO1A2 | c.1998G>A p.L666= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100261760; called by muse, mutect2, varscan2
- STRIP2 | c.384C>T p.A128= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99973758; called by muse, mutect2, varscan2
- STYXL1 | c.897T>C p.T299= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99951385; called by muse, mutect2, varscan2
- SUMO2 | c.261C>T p.F87= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs755530217, COSV100092048; called by muse, mutect2, varscan2
- SVEP1 | c.678G>A p.G226= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100237858; called by muse, mutect2, varscan2
- SVIL | c.2634A>T p.S878= (on ENST00000355867 / NM_021738.3; = p.S452= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV100881220; called by muse, mutect2, varscan2
- TAF3 | c.1317C>T p.S439= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as rs1454045453, COSV60205450; called by muse, mutect2, varscan2
- TAS2R38 | c.243C>T p.F81= | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as rs868972577, COSV71885320; called by muse, mutect2, varscan2
- TBL2 | c.891C>T p.V297= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV99979592; called by muse, mutect2, varscan2
- TGM7 | c.492A>T p.R164= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV101476847; called by muse, mutect2, varscan2
- THBS4 | c.888C>T p.F296= | Silent (SNP) | VAF 116/170 reads (68%) | catalogued as COSV100644257; called by muse, mutect2, varscan2
- THPO | c.909G>C p.L303= (on ENST00000649095 / NM_001290003.1; = p.L163= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV99201187; called by muse, mutect2, varscan2
- TIMELESS | c.591C>T p.G197= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV99973929; called by muse, mutect2, varscan2
- TMEM236 | c.858C>T p.N286= | Silent (SNP) | VAF 116/378 reads (31%) | called by muse, mutect2, varscan2
- TMEM37 | c.414C>T p.S138= | Silent (SNP) | VAF 226/291 reads (78%) | catalogued as rs1293196349, COSV99191564; called by muse, mutect2, varscan2
- TRBV5-1 | c.39C>T p.L13= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- TRHR | c.820C>T p.L274= | Silent (SNP) | VAF 116/306 reads (38%) | catalogued as COSV100304808; called by muse, mutect2, varscan2
- TRIM44 | c.705C>T p.I235= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs1389531663, COSV100195010; called by muse, mutect2, varscan2
- TRIM71 | c.2160G>A p.R720= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV101070420; called by muse, mutect2, varscan2
- TRPM2 | c.3840G>A p.R1280= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as COSV100308689; called by muse, mutect2, varscan2
- UGT1A3 | c.225C>T p.F75= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV59395259; called by muse, mutect2, varscan2
- VPS35L | c.2853G>A p.T951= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs779587859, COSV99220583; called by muse, mutect2, varscan2
- WRN | c.1386C>T p.S462= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99988891; called by muse, mutect2, varscan2
- ZBTB14 | c.726T>C p.N242= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs1242142057, COSV100813447; called by muse, mutect2, varscan2
- ZHX2 | c.378C>T p.S126= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs200640976; called by muse, mutect2, varscan2
- ZMYM3 | c.963G>T p.G321= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV100077772, COSV58740992; called by muse, mutect2, varscan2
- ZNF12 | c.1884A>T p.S628= (on ENST00000405858 / NM_016265.4; = p.S590= on NM_006956.3) | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100703675; called by muse, mutect2, varscan2
- ZNF284 | c.1401C>T p.A467= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV101398971; called by muse, mutect2, varscan2
- ZNF462 | c.3639G>A p.Q1213= | Silent (SNP) | VAF 251/363 reads (69%) | catalogued as COSV52933197; called by muse, mutect2, varscan2
- ZNF670 | c.274C>T p.L92= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as COSV100829233; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81147373 C>T | 5'Flank (SNP) | VAF 76/163 reads (47%) | called by muse, mutect2, varscan2
- AGR2 | c.-1C>T | 5'UTR (SNP) | VAF 16/40 reads (40%) | catalogued as rs748127944, COSV101290813; called by muse, mutect2, varscan2
- ANKRD10 | c.455+5395C>T | Intron (SNP) | VAF 131/181 reads (72%) | called by muse, mutect2, varscan2
- LEPR | c.2673+3160G>A | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as rs1252582947, COSV100756552; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4702C>T | Intron (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100446982; called by muse, mutect2, varscan2
- OBSCN | c.18662-1861T>G | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99476908; called by muse, mutect2, varscan2
- RAB3GAP2 | c.811+1716C>T | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99424672; called by muse, mutect2, varscan2
- SNORD115-41 | n.55C>T | RNA (SNP) | VAF 199/449 reads (44%) | called by muse, varscan2
- SNORD115-41 | n.67G>A | RNA (SNP) | VAF 140/432 reads (32%) | called by muse, varscan2
- SNRPB | c.686-134C>T | Intron (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100293298; called by muse, mutect2, varscan2
